Gene-level copy-number profile of tumor specimen TCGA-96-8169-01A from TCGA case TCGA-96-8169, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 67.6 years (24,674 days).
Specimen TCGA-96-8169-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.a32c66e7-6918-46e5-bf20-1198f5be50e7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-96-8169-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d2ff06a9-023e-4683-b815-0d9566b3c29a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 14,548; copy number 2: 31,616; copy number 3: 10,354; copy number 4: 3,133; copy number 5: 29; copy number 6: 81; copy number 8: 19; copy number 10: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-96-8169-01A-11D-2292-01): tumor purity 0.42, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 167 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:11,020,883–14,364,506, 60 genes, copy number 6: LINC02752, AC111188.1, AC111188.2, MTND5P21, KC877392.1, GALNT18, CSNK2A3, AC023946.1, AC104031.1, MIR4299, AC131935.2, AC131935.1, AC104383.1, MIR8070, USP47, H3P33, DKK3, LINC02547, AC124276.1, AC124276.2, MICAL2, MIR6124, AC079329.1, AC025300.1, PARVA, AC009806.1, AC107881.1, TEAD1, AC013549.3, AC013549.4, AC013549.2, AC013549.1, LINC00958, RASSF10-DT, RASSF10, AC013762.1, AC022878.1, ARNTL, RN7SKP151, BTBD10, AC021269.3, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2.
- chr11:68,460,731–71,539,209, 75 genes, copy number 6–10 (broad region; genes not listed).
- chr18:214,520–976,883, 29 genes, copy number 5 (within-gene range 2–5): THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1.
- chr18:11,447,756–11,523,087, 3 genes, copy number 8 (within-gene range 3–8): AP001109.1, LINC01928, LINC01255.

Autosomal genes at a single copy (total copy number 1): 12,440. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
